Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6J-01A from TCGA case TCGA-VQ-AA6J, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 75.3 years (27,506 days).
Specimen TCGA-VQ-AA6J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d169ce5b-0d98-4626-96d0-2956ace18935.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5aa86bc8-7dba-48e2-a5a7-b4e8dc73a2e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,369; copy number 1: 22,145; copy number 2: 30,093; copy number 3: 2,670; copy number 4: 1,302; copy number 5: 284; copy number 6: 174; copy number 8: 54; copy number 13: 170; copy number 17: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6J-01A-11D-A40Z-01): tumor purity 0.35, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 441 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:120,395,668–120,395,729, 1 gene: MIR198.
- chr5:56,260,333–78,294,698, 365 genes (within-gene range 0–1) (broad region; genes not listed).
- chr5:132,875,395–134,727,909, 54 genes (within-gene range 0–4): AFF4, AC010240.2, Y_RNA, ATP6V0E1P1, AC010240.3, AC010240.1, Y_RNA, ZCCHC10, AC113410.1, AC113410.5, AC113410.4, HSPA4, AC113410.3, AC113410.2, AC010307.2, AC010307.1, FSTL4, AC010307.3, AC010307.4, AC010608.1, MIR1289-2, AC010608.3, AC010608.2, AC005178.1, WSPAR, C5orf15, VDAC1, AC008608.2, AC008608.1, TCF7, SKP1, AC104109.3, PPP2CA, AC104109.4, MIR3661, AC104109.2, AC104109.1, CDKL3, UBE2B, AC109454.4, AC109454.2, CDKN2AIPNL, AC109454.1, AC109454.3, AC005355.1, RNU6-456P, LINC01843, RN7SL541P, AC005355.2, JADE2, SAR1B, RNU6-1311P, SEC24A, RNU6-1164P.
- chr6:453,391–477,829, 1 gene (within-gene range 0–1): AL512308.1.
- chr6:30,414,715–30,494,194, 6 genes: MICC, AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr7:36,146,842–36,148,024, 1 gene: AC078841.1.
- chr7:142,389,202–142,392,412, 2 genes: TRBV5-3, TRBV9.
- chr9:659,986–660,326, 1 gene: EIF1P1.
- chr14:89,290,205–89,409,469, 4 genes: CAP2P1, AL357093.2, AL357093.1, AL356805.1.
- chr14:89,417,354–89,419,793, 1 gene: FOXN3-AS1.
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–2): KRTAP9-6, KRTAP9-11P.
- chr20:15,021,553–15,280,873, 3 genes: RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 683 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:104,487,095–105,588,802, 17 genes, copy number 13–17 (within-gene range 1–17): AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1.
- chr6:105,904,373–113,140,870, 154 genes, copy number 13 (broad region; genes not listed).
- chr11:65,726,939–67,873,367, 138 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr11:68,612,899–73,397,474, 162 genes, copy number 5–8 (broad region; genes not listed).
- chr12:7,108,052–7,128,889, 3 genes, copy number 5 (within-gene range 2–5): C1RL-AS1, RBP5, RNU6-485P.
- chr13:58,527,655–58,531,026, 2 genes, copy number 5: RNY4P29, CTAGE16P.
- chr14:22,630,929–22,644,352, 1 gene, copy number 5 (within-gene range 1–5): OR6J1.
- chr20:41,136,960–48,410,716, 206 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
